Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OP, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OP-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: F

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: esophagus, distal third C15.5
pw 10/9/12

PROCEDURE: APMI

ADDENDUM REPORT TO REPORT ADDITIONAL MATERIAL:

Additional sections reveal an additional nine lymph nodes, negative for neoplasm. The final total is eleven lymph nodes negative for neoplasm. The remainder of the diagnosis remains unchanged.

PROCEDURE: APDX

Please see previous report for diagnostic details.

the signing staff pathologist, have personally examined and interpreted the slides from this case.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: F

PROCEDURE: SPHS

Esophageal adenocarcinoma, T1N1 tumor with one para tumoral lymph node.

PROCEDURE: SPGD

1. "Distal esophagus and proximal stomach." Received in formalin in a large container is a 4 cm length of esophagus and attached 7.5 x 11 cm portion of proximal stomach. Arising from the gastroesophageal junction is a 3.5 x 3 x 2.2 cm polypoid mass. A 1.5 cm length of tumor extends superior into the esophagus. This strip of tissue is 2.5 cm from the proximal surgical margin. The mass is 6 cm from the distal (stomach) surgical margin. The adventitia of the esophagus and the serosal surface of the stomach are unremarkable. The adventitia opposite the tumor is inked green. Esophageal and gastric mucosa is otherwise unremarkable. On serial, longitudinal sections, the tumor appears to erode through the mucosa, but not into the muscle. Please see gross photos.
1A. Proximal margin (en face). Frozen section control.
1B. Projection of tumor-like mucosa to normal esophageal mucosa (greatest proximal extent of tumor).
1C-D. One full thickness section of tumor at esophageal junction extending to normal mucosa proximally and distally, bisected.
1E-F. Full thickness section of tumor including tumor to proximal mucosa and distal mucosa at deepest invasion. Bisected.
1G-H. Three lymph nodes each.
2. "Cervical esophageal margin." Received in formalin in a small container is a 1 cm long section of esophagus, stapled at one end. Staple line is removed and specimen submitted en face with true margin down.

PROCEDURE: SPNI

ESOPHAGUS CARCINOMA

LOCATION: Gastroesophageal junction

SIZE: 3.5 x 3 x 2.2 cm

HAS IT BEEN TREATED PREOPERATIVELY: No

TYPE OF CARCINOMA: Adenocarcinoma arising in barrett's mucosa

DEPTH OF INVASION: Lamina propria

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: F

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/2

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

T1a NO

PROCEDURE: SPDX

1&2. Esophagus and proximal stomach, resection: Moderately differentiated adenocarcinoma arising in barrett's mucosa at the gastroesophageal junction (3.5 cm), confined to lamina propria. Two lymph nodes, negative for neoplasm (additional sections pending). Margins negative. Incidental leiomyoma. Please see template for details.

the signing staff pathologist, have personally examined and interpreted the slides from this case.

Criteria	Yes	NA
DBS Reviewed		

10/9/12

Source: NCI Genomic Data Commons file 0759569c-5657-435a-9b6f-c4f3d0341892 (TCGA-L5-A4OP.5A53A5CA-6F46-4F32-A616-E1469345F756.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).